Somatic mutation profile of tumor specimen TCGA-HT-7687-01A (aliquot TCGA-HT-7687-01A-11D-2253-08) from TCGA case TCGA-HT-7687, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 74.4 years (27,186 days).
Specimen TCGA-HT-7687-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fdfd6eba-f46a-482b-a3f0-04277ac04a37.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7687-10A (Blood Derived Normal), aliquot TCGA-HT-7687-10A-01D-2253-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b9a62ca7-3468-4c34-8acd-e2022f92effe

The open-access MAF lists 37 somatic variants for this specimen: 27 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 9, Splice Site 2, Frame Shift Del 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 59/147 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ANKRD17 | c.7588-2A>G p.X2530_splice | Splice Site (SNP) | VAF 7/47 reads (15%) | catalogued as COSV58222447; called by muse, mutect2
- C11orf42 | c.493G>C p.V165L | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV56412188; called by muse, mutect2
- CACNA1S | c.2099C>T p.T700M | Missense Mutation (SNP) | VAF 70/716 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs147112322; ClinVar: uncertain significance; called by muse, mutect2
- CNTN3 | c.1570C>A p.Q524K | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV55174666; called by muse, mutect2, varscan2
- CSTF1 | c.956A>G p.K319R | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV53859127; called by muse, mutect2
- DDX5 | c.440_441+2del p.X147_splice | Splice Site (DEL) | VAF 113/319 reads (35%) | catalogued as rs782442161; called by mutect2, pindel, varscan2
- EFCAB12 | c.1559C>T p.T520I | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV58176885; called by muse, mutect2
- GAREM1 | c.2258A>G p.E753G (on ENST00000269209 / NM_001242409.2; = p.E752G on NM_022751.3) | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV52511236; called by muse, mutect2, varscan2
- LDAH | c.93G>C p.W31C | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as COSV52971222; called by muse, mutect2, varscan2
- LRRC4B | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 54/83 reads (65%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.81); catalogued as rs1176894570, COSV65350257; called by muse, mutect2, varscan2
- MUC17 | c.5276C>T p.T1759M | Missense Mutation (SNP) | VAF 263/676 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.25); catalogued as rs766922764, COSV60292065; called by muse, mutect2, varscan2
- OPA1 | c.1289G>A p.C430Y (on ENST00000361510 / NM_130837.3; = p.C375Y on NM_015560.3) | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV62481373; called by muse, mutect2
- OPN5 | c.860T>A p.L287H | Missense Mutation (SNP) | VAF 70/201 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV55245986; called by muse, mutect2, varscan2
- OR2A14 | c.594del p.F199Lfs*27 | Frame Shift Del (DEL) | VAF 164/435 reads (38%) | catalogued as rs1423714091, COSV68718855; called by mutect2, pindel, varscan2
- OR4A16 | c.740T>C p.L247P | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV59043648; called by muse, mutect2, varscan2
- OR5K3 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 107/314 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs150899692, COSV67350205; called by muse, mutect2, varscan2
- PKD1L1 | c.2300G>C p.S767T | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56968229, COSV56980072; called by muse, mutect2, varscan2
- RALGDS | c.1669A>G p.T557A | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as COSV64427855; called by muse, mutect2, varscan2
- RANBP2 | c.5894A>G p.D1965G | Missense Mutation (SNP) | VAF 18/428 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV51702779; called by muse, mutect2
- TIAM1 | c.2114A>G p.K705R | Missense Mutation (SNP) | VAF 99/211 reads (47%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.985); catalogued as COSV54557072; called by muse, mutect2, varscan2
- TNN | c.3868C>T p.R1290W | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs750133414, COSV53428538; called by muse, mutect2, varscan2
- UEVLD | c.791A>T p.D264V | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV57875202; called by muse, mutect2
- VAX1 | c.373G>A p.V125M | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as COSV53327826; called by muse, mutect2, varscan2
- ZBTB18 | c.1412G>A p.C471Y | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62397574; called by muse, mutect2, varscan2
- GDF10 | c.1376A>G p.N459S | Missense Mutation (SNP) | VAF 10/266 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2
- ZNF292 | c.5112_5113del p.N1705Ffs*6 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | called by pindel, varscan2
- AHI1 | c.309C>T p.N103= | Silent (SNP) | VAF 94/199 reads (47%) | catalogued as rs920809603, COSV55629641; called by muse, mutect2, varscan2
- HIVEP3 | c.318G>A p.S106= | Silent (SNP) | VAF 111/163 reads (68%) | catalogued as rs371696795; called by muse, mutect2, varscan2
- HLA-DOA | c.474G>A p.V158= | Silent (SNP) | VAF 106/326 reads (33%) | catalogued as COSV57714645; called by muse, mutect2, varscan2
- MINK1 | c.2700T>C p.H900= | Silent (SNP) | VAF 47/167 reads (28%) | catalogued as COSV53418510; called by muse, mutect2, varscan2
- MYOM1 | c.2139C>T p.R713= | Silent (SNP) | VAF 4/66 reads (6%) | catalogued as COSV55293917; called by muse, mutect2
- MYT1L | c.1326G>A p.T442= | Silent (SNP) | VAF 78/198 reads (39%) | catalogued as rs746922049, COSV67710282; called by muse, mutect2, varscan2
- NAGPA | c.651A>G p.Q217= | Silent (SNP) | VAF 172/436 reads (39%) | catalogued as rs1336982621, COSV56570150; called by muse, mutect2, varscan2
- PDP2 | c.1389C>T p.L463= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV61240758; called by muse, mutect2, varscan2
- PRKD1 | c.1131C>T p.N377= | Silent (SNP) | VAF 110/318 reads (35%) | catalogued as rs980423990, COSV59561138; called by muse, mutect2, varscan2
- DEFB119 | c.61+1256G>A | Intron (SNP) | VAF 18/246 reads (7%) | catalogued as rs762049328, COSV59266391; called by muse, mutect2
